Somatic mutation profile of cancer-model specimen HCM-BROD-0095-C15-85A (3D Organoid, passage 4; aliquot HCM-BROD-0095-C15-85A-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0095-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 51.5 years (18,799 days).
Specimen HCM-BROD-0095-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05df8f66-658a-4d88-a54e-de0324788f61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0095-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0095-C15-10B-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00f15a51-5707-4974-a391-9d00ed68fb4f

The open-access MAF lists 91 somatic variants for this specimen: 62 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 26, Nonsense Mutation 6, 5'UTR 2, Frame Shift Del 1, Splice Site 1, In Frame Del 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 586/859 reads (68%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 283/283 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 119/388 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.096); catalogued as rs1260969411, COSV62815206; called by muse, mutect2, varscan2
- AP1S1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 295/766 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99973055; called by muse, mutect2, varscan2
- ARID1A | c.3331G>T p.E1111* | Nonsense Mutation (SNP) | VAF 351/352 reads (100%) | catalogued as COSV100249984; called by muse, mutect2, varscan2
- CBWD6 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1234122306; called by muse, mutect2, varscan2
- FAT4 | c.13543G>A p.A4515T | Missense Mutation (SNP) | VAF 155/369 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as rs369929089; called by muse, mutect2, varscan2
- GGA3 | c.1327G>A p.D443N (on ENST00000537686 / NM_138619.4; = p.D410N on NM_014001.5) | Missense Mutation (SNP) | VAF 259/506 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as rs781342118; called by muse, mutect2, varscan2
- JAK2 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 93/282 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1168347611; called by muse, mutect2, varscan2
- LAMA1 | c.8762G>A p.R2921Q | Missense Mutation (SNP) | VAF 143/449 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs371871409; called by muse, mutect2, varscan2
- LDB2 | c.91C>G p.R31G | Missense Mutation (SNP) | VAF 128/261 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58777805; called by muse, mutect2, varscan2
- MEGF8 | c.2353C>T p.R785C (on ENST00000251268 / NM_001271938.2; = p.R718C on NM_001410.3) | Missense Mutation (SNP) | VAF 402/643 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs746842471; called by muse, mutect2, varscan2
- METTL14 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 120/290 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs764385026, COSV66310980; called by muse, mutect2, varscan2
- MKI67 | c.9588C>A p.D3196E | Missense Mutation (SNP) | VAF 123/464 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs758356895; called by mutect2, varscan2
- MUC6 | c.6601_6603del p.S2201del | In Frame Del (DEL) | VAF 524/562 reads (93%) | catalogued as rs1296850164; called by pindel, varscan2
- MYO5A | c.4840G>A p.V1614M | Missense Mutation (SNP) | VAF 138/301 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs775270803, COSV62560537; called by muse, mutect2, varscan2
- OR51B2 | c.263G>A p.R88K | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100173368, COSV60915898; called by muse, mutect2, varscan2
- PERCC1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 435/436 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766752316; called by muse, mutect2, varscan2
- PHYHD1 | c.610C>T p.R204W (on ENST00000372592 / NM_001100876.2; = p.S196= on NM_174933.4) | Missense Mutation (SNP) | VAF 95/305 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369483059; called by muse, mutect2, varscan2
- PLCD3 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 627/628 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747851992; called by muse, mutect2, varscan2
- PLXNB1 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 203/813 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs769375183; called by muse, mutect2, varscan2
- RFTN2 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 82/420 reads (20%) | catalogued as rs1164246651, COSV54388642; called by muse, mutect2, varscan2
- RSF1 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs773402875; called by muse, mutect2, varscan2
- SEPTIN3 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 204/523 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs1324108685; called by muse, mutect2, varscan2
- TMEM184A | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 255/1118 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.391); catalogued as rs373942205; called by muse, mutect2, varscan2
- ZFHX2 | c.3565C>T p.R1189W | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406537400; called by muse, mutect2, varscan2
- ZNF141 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.352); catalogued as rs781825597; called by muse, mutect2, varscan2
- ADAM2 | c.891+1del p.X297_splice | Splice Site (DEL) | VAF 74/193 reads (38%) | called by mutect2, pindel, varscan2
- AKNA | c.3071C>G p.S1024* | Nonsense Mutation (SNP) | VAF 140/486 reads (29%) | called by muse, mutect2, varscan2
- AP3D1 | c.3007C>T p.Q1003* | Nonsense Mutation (SNP) | VAF 150/277 reads (54%) | called by muse, mutect2, varscan2
- ARMH2 | c.124_127delinsGA p.K42Efs*8 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by pindel, varscan2*
- ATP8B2 | c.2032G>T p.A678S (on ENST00000672630; = p.A645S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/520 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BRWD1 | c.948G>T p.K316N | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CREB5 | c.564G>A p.M188I (on ENST00000357727 / NM_182898.4; = p.M181I on NM_004904.3) | Missense Mutation (SNP) | VAF 237/483 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ELOF1 | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 265/444 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERVW-1 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 177/494 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA3 | c.2114T>A p.L705* | Nonsense Mutation (SNP) | VAF 96/175 reads (55%) | called by muse, mutect2, varscan2
- GRAMD1B | c.425T>G p.F142C | Missense Mutation (SNP) | VAF 130/246 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GREB1L | c.5191C>T p.R1731C | Missense Mutation (SNP) | VAF 118/351 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HOOK1 | c.805G>C p.D269H | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- INO80C | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- IRX1 | c.1283C>G p.A428G | Missense Mutation (SNP) | VAF 469/469 reads (100%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAB21L1 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 138/511 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NIPAL2 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 162/382 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOXO1 | c.838G>C p.G280R (on ENST00000397280 / NM_172168.3; = p.G274R on NM_144603.4) | Missense Mutation (SNP) | VAF 265/521 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OSR2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 118/242 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE8B | c.2087C>T p.T696M | Missense Mutation (SNP) | VAF 21/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PHOSPHO2 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SATL1 | c.1259_1266dup p.G423Hfs*9 (on ENST00000395409; = p.G610Hfs*9 on NM_001012980.2) | Frame Shift Ins (INS) | VAF 64/72 reads (89%) | called by mutect2, varscan2
- SORCS3 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 270/584 reads (46%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAT4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 146/300 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SYCN | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 111/594 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SYCP1 | c.2499A>C p.K833N | Missense Mutation (SNP) | VAF 161/290 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TLR4 | c.349T>A p.L117I (on ENST00000355622 / NM_138554.5; = p.L77I on NM_003266.4) | Missense Mutation (SNP) | VAF 122/376 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TMPPE | c.1095C>G p.I365M | Missense Mutation (SNP) | VAF 172/402 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- TTI2 | c.857A>G p.Y286C | Missense Mutation (SNP) | VAF 97/209 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TTN | c.50641G>C p.D16881H (on ENST00000591111; = p.D9457H on NM_003319.4) | Missense Mutation (SNP) | VAF 24/650 reads (4%) | PolyPhen possibly damaging (0.723); called by muse, mutect2
- UNC79 | c.7342G>T p.A2448S (on ENST00000393151 / NM_001346218.2; = p.A2271S on NM_020818.5) | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- YEATS2 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); called by muse, mutect2
- ZDHHC13 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 209/209 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF700 | c.126T>G p.D42E | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZNF723 | c.107A>T p.N36I | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- ADCY5 | c.1878C>T p.G626= | Silent (SNP) | VAF 23/463 reads (5%) | catalogued as rs759483120, COSV59202997; called by muse, mutect2
- BAHCC1 | c.2274G>A p.T758= | Silent (SNP) | VAF 28/412 reads (7%) | catalogued as rs369219361; called by muse, mutect2
- BAHCC1 | c.5187G>A p.S1729= | Silent (SNP) | VAF 253/470 reads (54%) | catalogued as rs555426689, COSV100312144; called by muse, mutect2, varscan2
- C7orf33 | c.528C>T p.S176= | Silent (SNP) | VAF 203/203 reads (100%) | called by muse, mutect2, varscan2
- CAGE1 | c.1176G>A p.T392= (on ENST00000512086; = p.T256= on NM_205864.3) | Silent (SNP) | VAF 236/236 reads (100%) | catalogued as rs1276257233; called by muse, mutect2, varscan2
- CHI3L2 | c.915T>C p.Y305= | Silent (SNP) | VAF 114/212 reads (54%) | catalogued as rs751297966; called by muse, mutect2, varscan2
- CYP2E1 | c.922C>T p.L308= | Silent (SNP) | VAF 137/297 reads (46%) | called by muse, mutect2, varscan2
- DNAJC14 | c.1437G>C p.R479= | Silent (SNP) | VAF 136/278 reads (49%) | called by muse, mutect2, varscan2
- FAT3 | c.7263A>G p.A2421= | Silent (SNP) | VAF 48/297 reads (16%) | called by muse, mutect2, varscan2
- FBXL19 | c.753G>A p.S251= | Silent (SNP) | VAF 439/439 reads (100%) | catalogued as rs752080541; called by muse, mutect2, varscan2
- FZD2 | c.1254G>A p.A418= | Silent (SNP) | VAF 168/314 reads (54%) | called by muse, varscan2
- LRRC28 | c.1080G>T p.L360= | Silent (SNP) | VAF 128/288 reads (44%) | catalogued as rs780004284; called by muse, mutect2, varscan2
- NELL1 | c.1749C>T p.D583= | Silent (SNP) | VAF 267/267 reads (100%) | catalogued as rs758011669, COSV100117908; called by muse, mutect2, varscan2
- NFKBID | c.375C>T p.A125= (on ENST00000396901; = p.A277= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 231/419 reads (55%) | catalogued as rs200569784, COSV61727887; called by muse, mutect2, varscan2
- PPP6R3 | c.519C>T p.I173= | Silent (SNP) | VAF 172/339 reads (51%) | catalogued as rs752092716; called by muse, mutect2, varscan2
- PRX | c.2172C>T p.L724= | Silent (SNP) | VAF 162/458 reads (35%) | called by muse, mutect2, varscan2
- RIN3 | c.2739C>T p.F913= | Silent (SNP) | VAF 291/657 reads (44%) | catalogued as rs374034469; called by muse, mutect2, varscan2
- SCUBE1 | c.2769C>T p.R923= | Silent (SNP) | VAF 210/371 reads (57%) | catalogued as rs201681235; called by muse, mutect2, varscan2
- TAS2R3 | c.462C>G p.L154= | Silent (SNP) | VAF 456/456 reads (100%) | called by muse, mutect2, varscan2
- THEM6 | c.549C>T p.H183= | Silent (SNP) | VAF 149/854 reads (17%) | called by muse, mutect2, varscan2
- TMEM41A | c.321G>A p.L107= | Silent (SNP) | VAF 256/776 reads (33%) | catalogued as rs1045639435; called by muse, mutect2, varscan2
- TMPPE | c.621C>G p.L207= | Silent (SNP) | VAF 154/323 reads (48%) | catalogued as rs920056427; called by muse, varscan2
- TMPPE | c.381C>A p.I127= | Silent (SNP) | VAF 147/286 reads (51%) | called by muse, varscan2
- TNRC6A | c.27C>G p.T9= | Silent (SNP) | VAF 120/280 reads (43%) | called by muse, mutect2, varscan2
- ZBTB2 | c.81G>A p.T27= | Silent (SNP) | VAF 339/339 reads (100%) | catalogued as rs771652540, COSV100287510; called by muse, mutect2, varscan2
- ZNF729 | c.3189T>A p.L1063= | Silent (SNP) | VAF 163/299 reads (55%) | called by muse, mutect2, varscan2
- CABP1 | c.655-3856G>A | Intron (SNP) | VAF 213/434 reads (49%) | called by muse, mutect2, varscan2
- FRS2 | c.-277C>T | 5'UTR (SNP) | VAF 179/353 reads (51%) | called by muse, mutect2, varscan2
- TLR9 | c.-468G>A | 5'UTR (SNP) | VAF 370/558 reads (66%) | called by muse, mutect2, varscan2
